Somatic mutation profile of tumor specimen MP2PRT-PAVLMU-TMP1-A (aliquot MP2PRT-PAVLMU-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVLMU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,978 days).
Specimen MP2PRT-PAVLMU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 605a2b38-15e4-4ecf-8d2b-58c72dbb8c82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVLMU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVLMU-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87f6faa9-07b2-4000-bca8-7f0b7e5ef3d8

The open-access MAF lists 104 somatic variants for this specimen: 72 protein-altering or splice-affecting, 25 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 25, Nonsense Mutation 10, Intron 4, Frame Shift Ins 2, 3'UTR 1, RNA 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.5664C>G p.F1888L | Missense Mutation (SNP) | VAF 22/429 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63869154, COSV63870934; called by muse, mutect2
- ADCK5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 46/510 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370821655; called by muse, mutect2
- ATM | c.7297C>T p.Q2433* | Nonsense Mutation (SNP) | VAF 53/145 reads (37%) | catalogued as COSV53756517; called by muse, mutect2, varscan2
- BTBD8 | c.2066C>T p.S689L (on ENST00000636805 / NM_001376131.1; = p.S176L on NM_015237.4) | Missense Mutation (SNP) | VAF 180/389 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs868456801; called by muse, mutect2, varscan2
- COL6A1 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 223/563 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs753485651, COSV62612049; called by muse, varscan2
- DNAH8 | c.4501C>T p.L1501F | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59462985; called by muse, mutect2, varscan2
- ECT2L | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 25/282 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs761862346; called by muse, mutect2
- ESR2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs774665914; called by muse, mutect2, varscan2
- F8 | c.7039G>A p.A2347T | Missense Mutation (SNP) | VAF 145/326 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as CM1212745; called by muse, mutect2, varscan2
- H2BC10 | c.20C>G p.S7* | Nonsense Mutation (SNP) | VAF 31/277 reads (11%) | catalogued as rs201737810; called by muse, mutect2, varscan2
- HERC2 | c.6380G>C p.R2127T | Missense Mutation (SNP) | VAF 179/400 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV99873561; called by muse, mutect2, varscan2
- HYDIN | c.10342G>C p.E3448Q | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV101153289; called by muse, mutect2, varscan2
- IFT140 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 18/349 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV68487721, COSV68505582; called by muse, mutect2
- IQSEC2 | c.2278G>A p.G760S (on ENST00000642864 / NM_001111125.3; = p.G555S on NM_015075.2) | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1556862958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1549 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as rs763996909, COSV54322919; called by muse, mutect2, varscan2
- LBP | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.701); catalogued as rs373530154, COSV99461594; called by muse, mutect2, varscan2
- MTUS1 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.935); catalogued as COSV50578202; called by muse, mutect2, varscan2
- NPAS3 | c.842C>T p.S281L (on ENST00000356141 / NM_001164749.2; = p.S249L on NM_022123.3) | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs140556633; called by muse, mutect2
- PEX13 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 25/398 reads (6%) | catalogued as rs146554084, CM111154; called by muse, mutect2
- PON3 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs374838987; called by muse, mutect2
- PRKAG2 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55233067; called by muse, mutect2
- PYROXD2 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 143/303 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs138840526; called by muse, mutect2, varscan2
- SCIN | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 139/487 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.47); catalogued as COSV51697942, COSV99765105; called by muse, mutect2, varscan2
- SERBP1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs767934992, COSV100769053; called by muse, mutect2
- SGK1 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 169/346 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV63116119; called by muse, mutect2, varscan2
- SLC44A5 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1177292269, COSV63771526; called by muse, mutect2, varscan2
- SLIT3 | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 187/445 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1449214831, COSV60602449; called by muse, mutect2, varscan2
- SPEG | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 202/461 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV56678077; called by muse, mutect2, varscan2
- TBCK | c.1621G>A p.D541N (on ENST00000273980 / NM_001163436.4; = p.D478N on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs761185647; called by muse, mutect2, varscan2
- UHRF1 | c.1394dup p.Y466Lfs*2 (on ENST00000612630 / NM_001290050.1; = p.Y479Lfs*2 on NM_013282.4) | Frame Shift Ins (INS) | VAF 79/160 reads (49%) | catalogued as rs1167678868; called by mutect2, pindel, varscan2
- ZIK1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.629); catalogued as COSV56737287; called by muse, mutect2, varscan2
- ZNF106 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1489105077; called by muse, mutect2, varscan2
- ZNF594 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 121/272 reads (44%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); catalogued as COSV101280479; called by muse, mutect2, varscan2
- ABCA5 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ACTR1B | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, varscan2
- ACY3 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 151/343 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- AFAP1 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 152/341 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- AKAP6 | c.4068G>T p.M1356I | Missense Mutation (SNP) | VAF 116/390 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGEF3 | c.1463C>G p.S488* | Nonsense Mutation (SNP) | VAF 170/348 reads (49%) | called by muse, mutect2, varscan2
- ARMH4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 164/353 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ASB1 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFH | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 17/178 reads (10%) | called by muse, mutect2, varscan2
- COL2A1 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL4A1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 118/278 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK2A2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- DCN | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELK1 | c.1230C>G p.I410M | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); called by muse, mutect2
- FRAS1 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GRIN2C | c.2549C>T p.S850L | Missense Mutation (SNP) | VAF 188/476 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- HCFC2 | c.1064-1G>C p.X355_splice | Splice Site (SNP) | VAF 63/154 reads (41%) | called by muse, varscan2
- IGHG3 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 143/498 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIG3 | c.3194G>A p.R1065K | Missense Mutation (SNP) | VAF 27/356 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- NCOA5 | c.1200G>C p.K400N | Missense Mutation (SNP) | VAF 240/507 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NUP210L | c.5579C>T p.S1860F | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- OFD1 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 133/293 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR56A5 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 150/358 reads (42%) | called by muse, mutect2, varscan2
- PAEP | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PRKDC | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBBP4 | c.464C>G p.T155R | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SERPINA6 | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 36/480 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2
- SHANK2 | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2
- SIRPD | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 40/410 reads (10%) | called by muse, mutect2
- SLC19A2 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 151/438 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD15 | c.4345C>A p.Q1449K | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TIMM17A | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 136/325 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TSHB | c.409dup p.S137Ffs*7 | Frame Shift Ins (INS) | VAF 84/243 reads (35%) | called by mutect2, pindel, varscan2
- TTN | c.87506C>G p.S29169* (on ENST00000591111; = p.S21745* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 186/390 reads (48%) | called by muse, mutect2, varscan2
- UGT1A10 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- WDR25 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 144/370 reads (39%) | called by muse, mutect2, varscan2
- ZNF10 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 127/340 reads (37%) | called by muse, mutect2, varscan2
- ZNF408 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 166/410 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF654 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ALS2 | c.3999A>G p.R1333= | Silent (SNP) | VAF 86/198 reads (43%) | called by muse, mutect2, varscan2
- ANGPT1 | c.762G>A p.L254= | Silent (SNP) | VAF 77/221 reads (35%) | catalogued as COSV52437816; called by muse, mutect2, varscan2
- ARMC2 | c.1782G>A p.Q594= | Silent (SNP) | VAF 34/498 reads (7%) | catalogued as rs1262858968; called by muse, mutect2
- COL27A1 | c.3738G>A p.G1246= | Silent (SNP) | VAF 128/324 reads (40%) | catalogued as rs531450041, COSV61927017; called by muse, mutect2
- DIAPH2 | c.1365G>A p.Q455= | Silent (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- DNAH3 | c.6975C>T p.F2325= | Silent (SNP) | VAF 150/345 reads (43%) | catalogued as COSV54514151; called by muse, mutect2, varscan2
- DYSF | c.2793C>T p.F931= | Silent (SNP) | VAF 25/216 reads (12%) | catalogued as rs146006518; ClinVar: likely benign; called by muse, mutect2, varscan2
- EHD3 | c.456C>T p.I152= | Silent (SNP) | VAF 54/402 reads (13%) | catalogued as rs61749077, COSV100434756; called by muse, mutect2, varscan2
- ELN | c.6G>A p.A2= | Silent (SNP) | VAF 45/512 reads (9%) | catalogued as rs782540463; ClinVar: likely benign; called by muse, mutect2
- JAK1 | c.591C>T p.I197= | Silent (SNP) | VAF 160/354 reads (45%) | called by muse, mutect2, varscan2
- LONRF3 | c.504C>T p.P168= | Silent (SNP) | VAF 238/509 reads (47%) | catalogued as rs751175464, COSV59152092, COSV59157176; called by muse, mutect2, varscan2
- LRRC63 | c.759G>C p.V253= | Silent (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- NOL4 | c.1224G>A p.L408= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as rs1257647495, COSV52365510; called by muse, mutect2
- PGLYRP2 | c.1419C>T p.H473= | Silent (SNP) | VAF 61/618 reads (10%) | called by muse, mutect2, varscan2
- PRSS12 | c.30G>C p.L10= | Silent (SNP) | VAF 132/306 reads (43%) | called by muse, mutect2, varscan2
- PTPRF | c.2226C>T p.R742= | Silent (SNP) | VAF 138/395 reads (35%) | catalogued as rs770030854, COSV63444750; called by muse, mutect2, varscan2
- RHBDL3 | c.105G>C p.P35= | Silent (SNP) | VAF 116/317 reads (37%) | called by muse, mutect2, varscan2
- SLC38A10 | c.534C>T p.F178= | Silent (SNP) | VAF 157/391 reads (40%) | called by muse, mutect2, varscan2
- SLITRK4 | c.1665G>A p.V555= | Silent (SNP) | VAF 177/418 reads (42%) | called by muse, mutect2, varscan2
- SP140 | c.1593C>G p.V531= | Silent (SNP) | VAF 76/200 reads (38%) | catalogued as COSV59455984; called by muse, mutect2, varscan2
- SPAG17 | c.4300C>A p.R1434= | Silent (SNP) | VAF 78/160 reads (49%) | catalogued as COSV60459020; called by muse, mutect2, varscan2
- TBC1D22A | c.975C>T p.L325= | Silent (SNP) | VAF 124/265 reads (47%) | catalogued as rs756620844; called by muse, mutect2, varscan2
- TET1 | c.3789C>T p.L1263= | Silent (SNP) | VAF 157/406 reads (39%) | catalogued as rs367864439, COSV65387604; called by muse, mutect2, varscan2
- TLE7 | c.465C>G p.L155= | Silent (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- ZNFX1 | c.3495C>T p.F1165= | Silent (SNP) | VAF 43/375 reads (11%) | catalogued as COSV100872629; called by muse, mutect2, varscan2
- ATAD3B | c.*511G>A | 3'UTR (SNP) | VAF 34/450 reads (8%) | catalogued as COSV58021404; called by muse, mutect2
- DCHS2 | n.8552G>A | RNA (SNP) | VAF 189/434 reads (44%) | catalogued as rs368291883; called by muse, mutect2, varscan2
- DGKB | c.2307+10G>A | Intron (SNP) | VAF 30/263 reads (11%) | catalogued as COSV51794711; called by muse, mutect2, varscan2
- DST | c.4297-4789A>G | Intron (SNP) | VAF 86/205 reads (42%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-33793G>A | Intron (SNP) | VAF 23/218 reads (11%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46680G>A | Intron (SNP) | VAF 22/392 reads (6%) | catalogued as rs1210094974; called by muse, mutect2
- MAGT1 | chrX:77895459 G>C | 5'Flank (SNP) | VAF 142/421 reads (34%) | catalogued as COSV63781501; called by muse, mutect2, varscan2
